Gene-level copy-number profile of tumor specimen C3N-03204-01 from CPTAC case C3N-03204, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 62.0 years (22,652 days).
Specimen C3N-03204-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2c319d8c-632a-4219-896d-21c324e76b57.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03204-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/13ef0768-c869-4adf-b8d8-2c93257c3eba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 26,650; copy number 2: 28,808; copy number 3: 2,616; copy number 4: 502; copy number 5: 213; copy number 6: 18; copy number 7: 49; copy number 8: 2; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr5:177,801,204–177,803,344, 1 gene: AC140125.1.
- chr8:8,116,745–8,116,949, 1 gene: SNRPCP17.
- chr9:64,817,870–64,836,341, 1 gene: AL359955.1.
- chr11:112,967–186,136, 5 genes (within-gene range 0–1): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr11:313,506–404,908, 10 genes: IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4, PKP3.
- chr15:19,955,300–19,988,117, 5 genes: AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7.
- chr15:43,593,054–43,684,339, 9 genes: CKMT1B, STRC, RNU6-554P, AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2, AC011330.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 286 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,631,389–189,897,276, 1 gene, copy number 5 (within-gene range 4–5): TP63.
- chr3:189,829,922–198,123,232, 203 genes, copy number 5 (broad region; genes not listed).
- chr5:23,262,159–28,287,807, 49 genes, copy number 6–12: AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, RNU4-43P, AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103.
- chr5:28,614,613–28,654,531, 2 genes, copy number 12: AC109472.1, RNU6-909P.
- chr7:54,419,444–55,713,252, 25 genes, copy number 5–7: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr14:18,333,726–18,412,264, 3 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2.
- chr21:12,999,676–13,067,033, 3 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 23,804. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
